Somatic mutation profile of tumor specimen TCGA-E8-A242-01A (aliquot TCGA-E8-A242-01A-21D-A16O-08) from TCGA case TCGA-E8-A242, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 56.0 years (20,472 days).
Specimen TCGA-E8-A242-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55569998-fc0e-4cfa-b03e-d443004eb029.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A242-10A (Blood Derived Normal), aliquot TCGA-E8-A242-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70dd4dbd-d226-4fc5-829c-43857ceb4dd5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DOK1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV51212904; called by muse, mutect2
- HEATR5A | c.5516C>T p.T1839I | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs1335070042, COSV66344904; called by muse, mutect2, varscan2
- KBTBD3 | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV73241599; called by muse, mutect2, varscan2
- KDM3A | c.2239A>G p.I747V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57225152; called by muse, mutect2, varscan2
- MLIP | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51425396, COSV51435839; called by muse, mutect2
- NALCN | c.2027G>C p.C676S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1345503450, COSV51961063; called by muse, mutect2
- SP140L | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs1206073390, COSV54747448; called by muse, mutect2, varscan2
- TTI1 | c.2958C>G p.V986= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as rs748271065, COSV65062196; called by muse, mutect2, varscan2
